Surgical pathology report (de-identified scan), TCGA case TCGA-CM-4751, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-4751-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

Clinical Diagnosis & History:

Had colonoscopy post GI bleed, required bleed treatment; cecal carcinoma.

Specimens Submitted:

- 1: SP: Omentum
- 2: SP: Right colon

DIAGNOSIS:

- 1. OMENTUM; OMENECTOMY:
- BENIGN ADIPOSE TISSUE.
- 2. COLON, APPENDIX AND TERMINAL ILEUM; RIGHT HEMICOLECTOMY:
- ADENOCARCINOMA, MODERATELY DIFFERENTIATED, OF CECUM.
- THE TUMOR MEASURES 3.0 X 4.7 X. 0.8 CM.
- THE GROSS CONFIGURATION IS ULCERATIVE.
- NO PRE-EXISTING TUBULAR ADENOMA.
- THE TUMOR INVADES INTO SUBSEROA, pT3.
- NO GROSS PERFORATION IS IDENTIFIED.
- NO SEROSAL INVOLVEMENT IS IDENTIFIED.
- VASCULAR INVASION IS IDENTIFIED.
- NO PERINEURAL INVASION IS IDENTIFIED.
- ALL SURGICAL MARGINS OF RESECTION ARE FREE OF TUMOR.
- MULTIPLE ADDITIONAL TUBULAR ADENOMAS (\R\20) ARE IDENTIFIED.
- THE NON-NEOPLASTIC COLON, ILEUM, AND THE APPENDIX ARE UNREMARKABLE.
- LYMPH NODES: NUMBER WITH METASTASES: 3; NUMBER EXAMINED: 48 (3/48)
- pN1.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

Gross Description:

** Continued on next page **

[page 2 of 3]
1). The specimen is received fresh, labeled "Omentum." It consists of a 21 x 14 x 1.5 cm fragment of adipose tissue consistent with omentum. Serial sectioning reveals tan-yellow lobulated adipose tissue. No discrete lesions or abnormalities are grossly identified. Representative sections are submitted.

Summary of sections:

U - omentum

2). The specimen is received fresh, labeled "Right colon" and consists of a segment of terminal ileum, cecum with attached appendix and ascending colon. The terminal ileum measures 14.0 cm in length and 3.7 cm in circumference at the proximal resected margin. The remaining colon measures 33.5 cm in length with a circumference of 8.5 cm at the distal resected margin. The attached appendix measures 6.0 cm in length and averages 1.0 cm in diameter. The appendiceal serosa is pink tan and the wall at the tip is partially thickened. Focally hemorrhagic lobulated yellow tan adipose tissue spans the length of the specimen measuring up to 3.0 cm in thickness. The intestinal serosa around decal pouch displays a 6.0 x 4.0 cm hemorrhagic puckered focus. This area and the surrounding pericolic adipose tissue are inked blue. The specimen is opened to reveal an underlying ulcerated tumor measuring 3.0 cm in length and 4.7 cm in width, that is 2.0 cm from the ileocecal valve and 24.5 cm from the distal colon margin. Sectioning shows that the tumor invades into a depth of 0.8 cm, grossly involving through the muscularis and approaching the serosa. The remaining mucosa is tan pink and displays approximately 20 smooth sessile polyps ranging from 0.3 cm to 1.2 cm in greatest dimension. All the polyps over 1.0 cm are submitted entirely and representative sections of the remaining specimen are submitted. Multiple lymph nodes are identified in the attached adipose tissue and are submitted. A portion of the specimen is submitted for TPS.

Summary of sections:

PM-- proximal margin shave

DM -- distal margin shave

A -- appendix representative sections to include entire distal tip

T-- tumor

TI -- tumor in deepest invasion

P1, P2, P3, P4 -- polyps over 1.0 cm in greatest dimension

RS--representative sections

LN-- lymph nodes

BLN bisected lymph node

TLNtrisected lymph node

Summary of Sections:

Part 1: SP: Omentum

** Continued on next page **

[page 3 of 3]
Block	Sect.	Site	PCs
2		u	2

Part 2: SP: Right colon

Block	Sect.	Site	PCs
2		A	2
6		BLN	6
2		DM	2
7		LN	7
1		P1	1
1		P2	1
1		P3	1
1		P4	1
2		PM	2
2		RS	2
3		T	3
1		TI	1

** End of Report **

Source: NCI Genomic Data Commons file adc65821-648f-480c-b8ce-521766891abf (TCGA-CM-4751.C1B8B7F6-BFDC-4E4F-BE9A-5B752390EFC0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).